Somatic mutation profile of tumor specimen MMRF_1842_1_BM_CD138pos (aliquot MMRF_1842_1_BM_CD138pos_T1_KBS5U_L05773) from MMRF case MMRF_1842, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 56.2 years (20,514 days).
Specimen MMRF_1842_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0f3943a2-f612-438a-832b-5362a37d75cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1842_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1842_1_PB_Whole_C3_KBS5U_L05799; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/01b4c3d6-6860-4a13-81be-8ad480c6bd86

The open-access MAF lists 131 somatic variants for this specimen: 58 protein-altering or splice-affecting, 18 silent, 55 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, 3'UTR 28, Silent 18, Intron 11, 5'UTR 9, 5'Flank 5, Nonsense Mutation 2, 3'Flank 2, Splice Site 2, Splice Region 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- ADGRV1 | c.17019G>T p.K5673N | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); catalogued as COSV101315274; called by muse, mutect2, varscan2
- ALDH4A1 | c.907G>A p.D303N | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as rs1264192425; called by muse, mutect2, varscan2
- CYLC2 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 86/192 reads (45%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as COSV66339172; called by muse, mutect2, varscan2
- DISP3 | c.2812G>A p.A938T | Missense Mutation (SNP) | VAF 73/137 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.464); catalogued as rs759615246, COSV53821020; called by muse, mutect2, varscan2
- DNER | c.1865G>A p.W622* | Nonsense Mutation (SNP) | VAF 33/54 reads (61%) | catalogued as COSV59167901; called by muse, mutect2, varscan2
- DNMT3A | c.2207G>A p.R736H | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.874); catalogued as rs139293773, COSV53036512, COSV53049625, COSV53069747; called by muse, mutect2, varscan2
- FAT4 | c.11212A>G p.I3738V | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs1161046080; called by muse, mutect2, varscan2
- GPR149 | c.1625G>A p.R542H | Missense Mutation (SNP) | VAF 64/134 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs199967865, COSV67667010; called by muse, mutect2, varscan2
- GRIP1 | c.1128C>G p.N376K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as COSV54036728; called by muse, mutect2, varscan2
- IGHV2-70D | c.148A>G p.T50A | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as rs1292545219; called by muse, varscan2
- IGHV3-53 | c.275A>G p.N92S | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.725); catalogued as rs1555545005; called by muse, varscan2
- IGHV3-53 | c.173A>G p.Q58R | Missense Mutation (SNP) | VAF 80/104 reads (77%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.603); catalogued as rs782464921; called by muse, varscan2
- IGHV3-53 | c.161G>A p.S54N | Missense Mutation (SNP) | VAF 76/100 reads (76%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.01); catalogued as rs577073983; called by muse, varscan2
- IGKV4-1 | c.153C>G p.Y51* | Nonsense Mutation (SNP) | VAF 56/58 reads (97%) | catalogued as rs762957191; called by muse, mutect2, varscan2
- IGKV4-1 | c.353A>G p.Y118C | Missense Mutation (SNP) | VAF 43/44 reads (98%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.955); catalogued as rs572656022; called by muse, mutect2, varscan2
- IGLL5 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.029); catalogued as rs1312597802, COSV73248993, COSV73250846; called by muse, varscan2
- IGLL5 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.009); catalogued as rs752528433, COSV73248970, COSV73250847; called by muse, varscan2
- IGLV3-1 | c.124T>C p.S42P | Missense Mutation (SNP) | VAF 55/104 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); catalogued as rs573800830; called by muse, varscan2
- KIF13B | c.4469G>A p.R1490H | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as rs767471422, COSV68094512; called by muse, mutect2, varscan2
- MSH4 | c.1630G>A p.D544N | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as rs773595661; called by muse, mutect2, varscan2
- OR3A1 | c.166C>A p.P56T | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs1471314499; called by muse, mutect2, varscan2
- RGS20 | c.577G>A p.A193T (on ENST00000297313 / NM_170587.4; = p.A46T on NM_003702.4) | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs139887382, COSV99391907; called by muse, mutect2, varscan2
- TCTEX1D4 | c.631G>A p.A211T | Missense Mutation (SNP) | VAF 75/163 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1298092277; called by muse, mutect2, varscan2
- TINAG | c.567A>T p.K189N | Missense Mutation (SNP) | VAF 96/201 reads (48%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs758756157, COSV52505411; called by muse, mutect2, varscan2
- TNN | c.2662C>G p.P888A | Missense Mutation (SNP) | VAF 33/106 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53436193; called by muse, mutect2, varscan2
- UHRF2 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs757909807, COSV52791153; called by muse, mutect2, varscan2
- ABCA12 | c.2576C>T p.A859V (on ENST00000272895 / NM_173076.3; = p.A541V on NM_015657.3) | Missense Mutation (SNP) | VAF 96/197 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AGTR1 | c.894T>A p.N298K | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BAZ1B | c.572-1G>A p.X191_splice | Splice Site (SNP) | VAF 10/21 reads (48%) | called by muse, mutect2
- CFHR5 | c.532A>T p.N178Y | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.226); called by muse, mutect2, varscan2
- CLUH | c.1661T>G p.I554S (on ENST00000435359; = p.I592S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTN4 | c.1486+8C>A | Splice Region (SNP) | VAF 17/80 reads (21%) | called by muse, mutect2, varscan2
- DNAH9 | c.12171C>A p.F4057L | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FAM135B | c.484T>C p.S162P | Missense Mutation (SNP) | VAF 65/171 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FGFR2 | c.2183G>T p.C728F | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FMNL1 | c.174G>C p.Q58H | Missense Mutation (SNP) | VAF 15/157 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2
- FOXK2 | c.1607A>T p.H536L | Missense Mutation (SNP) | VAF 63/117 reads (54%) | SIFT tolerated (0.68); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- GFRA4 | c.380G>A p.S127N | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0.191); called by muse, mutect2
- HOXC13 | c.799T>G p.Y267D | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HP | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- HSPA4L | c.2210T>C p.V737A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- IGHV2-70D | c.171_172insCTGCTGG p.I58Lfs*18 | Frame Shift Ins (INS) | VAF 30/72 reads (42%) | called by pindel, varscan2
- MYLIP | c.399G>C p.Q133H | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- NAV3 | c.5929A>C p.S1977R (on ENST00000397909 / NM_001024383.2; = p.S1955R on NM_014903.6) | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2, varscan2
- NEB | c.10232G>C p.G3411A | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUMA1 | c.648G>C p.M216I | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR6C75 | c.815T>A p.V272E | Missense Mutation (SNP) | VAF 109/238 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR8D1 | c.593T>A p.L198Q | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PRR9 | c.309G>C p.Q103H | Missense Mutation (SNP) | VAF 35/67 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- RYR2 | c.5474T>A p.F1825Y | Missense Mutation (SNP) | VAF 54/111 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- SLC4A7 | c.3333+2T>G p.X1111_splice | Splice Site (SNP) | VAF 54/204 reads (26%) | called by muse, mutect2, varscan2
- TLR4 | c.1858G>T p.V620L (on ENST00000355622 / NM_138554.5; = p.V580L on NM_003266.4) | Missense Mutation (SNP) | VAF 76/176 reads (43%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TMEM132E | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- TMEM92 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TRPS1 | c.3763A>C p.K1255Q (on ENST00000220888 / NM_001330599.2; = p.K1268Q on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 79/156 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- TSPAN32 | c.585_592del p.Q195Hfs*81 | Frame Shift Del (DEL) | VAF 52/95 reads (55%) | called by mutect2, pindel, varscan2
- ZBTB40 | c.2626G>A p.A876T | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- ARHGEF1 | c.1617C>T p.F539= | Silent (SNP) | VAF 65/128 reads (51%) | called by muse, mutect2, varscan2
- CARD6 | c.54G>A p.L18= | Silent (SNP) | VAF 74/154 reads (48%) | called by muse, mutect2, varscan2
- DYNC2LI1 | c.855T>A p.P285= | Silent (SNP) | VAF 21/80 reads (26%) | called by muse, mutect2, varscan2
- EMCN | c.108A>C p.T36= | Silent (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- IGHV2-70D | c.102A>G p.T34= | Silent (SNP) | VAF 32/68 reads (47%) | called by muse, varscan2
- IGHV2-70D | c.78T>C p.S26= | Silent (SNP) | VAF 40/78 reads (51%) | called by muse, varscan2
- IGHV2-70D | c.67T>C p.L23= | Silent (SNP) | VAF 38/76 reads (50%) | called by muse, varscan2
- MAF | c.93A>G p.E31= | Silent (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- MLLT10 | c.810T>A p.T270= | Silent (SNP) | VAF 16/64 reads (25%) | called by muse, mutect2, varscan2
- NR3C2 | c.1278A>G p.P426= | Silent (SNP) | VAF 59/101 reads (58%) | catalogued as COSV60990056; called by muse, mutect2, varscan2
- PTGFR | c.186C>A p.S62= | Silent (SNP) | VAF 67/133 reads (50%) | called by muse, mutect2, varscan2
- RIT2 | c.240A>G p.E80= | Silent (SNP) | VAF 6/81 reads (7%) | called by muse, mutect2
- SFXN3 | c.558A>G p.A186= | Silent (SNP) | VAF 89/183 reads (49%) | called by muse, mutect2, varscan2
- SOWAHD | c.753C>T p.S251= | Silent (SNP) | VAF 3/27 reads (11%) | called by muse, mutect2
- THSD4 | c.2616G>A p.T872= | Silent (SNP) | VAF 41/83 reads (49%) | catalogued as rs371091570; called by muse, mutect2, varscan2
- UBR4 | c.9984C>T p.C3328= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs201979796; called by muse, mutect2, varscan2
- UMODL1 | c.1995G>T p.R665= (on ENST00000408910 / NM_001004416.2; = p.R793= on NM_173568.3) | Silent (SNP) | VAF 34/269 reads (13%) | catalogued as COSV100210876; called by muse, mutect2, varscan2
- WSCD1 | c.174C>T p.A58= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as rs781226651, COSV58496352; called by muse, mutect2, varscan2
- ADAM12 | c.-141G>A | 5'UTR (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2
- AMDHD2 | c.1141+14G>A | Intron (SNP) | VAF 6/13 reads (46%) | catalogued as rs370224442; called by muse, mutect2, varscan2
- BBIP1 | c.38-5962C>T | Intron (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- CASC3 | c.*1614T>A | 3'UTR (SNP) | VAF 61/120 reads (51%) | called by muse, mutect2, varscan2
- CHRNB2 | c.*3133C>A | 3'UTR (SNP) | VAF 7/115 reads (6%) | called by muse, mutect2
- CNTN5 | c.*1105T>G | 3'UTR (SNP) | VAF 63/121 reads (52%) | called by muse, mutect2, varscan2
- COL27A1 | c.*1603G>A | 3'UTR (SNP) | VAF 36/95 reads (38%) | catalogued as rs559665636; called by muse, mutect2, varscan2
- COX5A | c.*118T>C | 3'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- CRNKL1 | c.*1037G>A | 3'UTR (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- CTBP1 | chr4:1249790 C>T | 5'Flank (SNP) | VAF 9/63 reads (14%) | called by muse, mutect2, varscan2
- DPP6 | c.-285A>G | 5'UTR (SNP) | VAF 59/195 reads (30%) | called by muse, mutect2, varscan2
- DYRK1A | c.-76-787del | Intron (DEL) | VAF 25/63 reads (40%) | called by mutect2, pindel, varscan2
- ETFBKMT | c.*2820T>A | 3'UTR (SNP) | VAF 24/79 reads (30%) | called by muse, mutect2, varscan2
- FERMT2 | c.1603-505A>G | Intron (SNP) | VAF 44/84 reads (52%) | called by muse, mutect2, varscan2
- G3BP1 | c.*3191A>C | 3'UTR (SNP) | VAF 19/65 reads (29%) | called by muse, mutect2, varscan2
- GULP1 | c.843+2504G>A | Intron (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- H4C4 | c.-4C>T | 5'UTR (SNP) | VAF 43/99 reads (43%) | catalogued as rs753095005; called by muse, mutect2, varscan2
- HAUS2 | c.*2501A>T | 3'UTR (SNP) | VAF 4/32 reads (13%) | catalogued as rs1177398457, COSV53000858; called by muse, varscan2
- HDGFL1 | c.*43G>A | 3'UTR (SNP) | VAF 60/135 reads (44%) | called by muse, mutect2, varscan2
- HTR5A | chr7:155068314 C>A | 5'Flank (SNP) | VAF 16/33 reads (48%) | called by muse, mutect2, varscan2
- IGFBP3 | chr7:45921657 C>T | 5'Flank (SNP) | VAF 61/126 reads (48%) | catalogued as rs1047885272; called by muse, mutect2, varscan2
- JADE1 | c.*2365G>C | 3'UTR (SNP) | VAF 69/167 reads (41%) | called by muse, mutect2, varscan2
- KBTBD11 | c.*3425A>C | 3'UTR (SNP) | VAF 28/80 reads (35%) | called by muse, mutect2, varscan2
- KCNJ11 | chr11:17388970 C>T | 5'Flank (SNP) | VAF 28/48 reads (58%) | called by muse, mutect2, varscan2
- KLF3 | c.*3385T>G | 3'UTR (SNP) | VAF 8/70 reads (11%) | called by muse, mutect2, varscan2
- KPNA6 | c.-37T>G | 5'UTR (SNP) | VAF 41/133 reads (31%) | called by muse, mutect2, varscan2
- LONRF2 | c.*5936C>A | 3'UTR (SNP) | VAF 25/92 reads (27%) | catalogued as COSV66542026; called by muse, mutect2, varscan2
- MIR5195 | chr14:106851315 C>G | 5'Flank (SNP) | VAF 64/137 reads (47%) | catalogued as rs537569481; called by muse, mutect2, varscan2
- NECTIN1 | c.*1649G>A | 3'UTR (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- NGB | c.-139C>T | 5'UTR (SNP) | VAF 3/10 reads (30%) | catalogued as rs1163808888; called by muse, mutect2
- NPC2 | chr14:74476452 A>G | 3'Flank (SNP) | VAF 27/90 reads (30%) | catalogued as rs1489862118; called by muse, mutect2, varscan2
- PCDHA10 | c.2388+2940C>T | Intron (SNP) | VAF 27/81 reads (33%) | catalogued as COSV56484333; called by muse, mutect2, varscan2
- PCDHB8 | c.-156G>C | 5'UTR (SNP) | VAF 69/239 reads (29%) | called by muse, mutect2, varscan2
- PEX11A | c.*1399G>C | 3'UTR (SNP) | VAF 81/171 reads (47%) | called by muse, mutect2, varscan2
- PEX5L | c.*2570dup | 3'UTR (INS) | VAF 30/70 reads (43%) | called by mutect2, pindel, varscan2
- PPP2R5E | c.*2135T>A | 3'UTR (SNP) | VAF 9/187 reads (5%) | catalogued as COSV61740882; called by muse, mutect2
- PRKCI | c.*1997T>A | 3'UTR (SNP) | VAF 10/212 reads (5%) | called by muse, mutect2
- PXN | c.*798C>T | 3'UTR (SNP) | VAF 22/59 reads (37%) | catalogued as rs774128735; called by muse, mutect2, varscan2
- SDAD1 | c.*681T>G | 3'UTR (SNP) | VAF 75/167 reads (45%) | called by muse, mutect2, varscan2
- SESN2 | c.*5T>C | 3'UTR (SNP) | VAF 90/221 reads (41%) | called by muse, mutect2, varscan2
- SIAH2 | c.-6A>G | 5'UTR (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- SRGAP1 | c.*573C>G | 3'UTR (SNP) | VAF 32/80 reads (40%) | called by muse, mutect2
- SUPT16H | c.159+646G>T | Intron (SNP) | VAF 77/177 reads (44%) | catalogued as rs1231376408; called by muse, mutect2, varscan2
- SYT1 | c.*2263A>G | 3'UTR (SNP) | VAF 36/81 reads (44%) | called by muse, mutect2, varscan2
- THSD4 | c.*2656A>G | 3'UTR (SNP) | VAF 46/99 reads (46%) | called by muse, mutect2, varscan2
- TMSB4X | c.-17+112C>T | Intron (SNP) | VAF 70/71 reads (99%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.*1977C>T | 3'UTR (SNP) | VAF 46/103 reads (45%) | called by muse, mutect2, varscan2
- TRIO | c.157+40021C>T | Intron (SNP) | VAF 30/68 reads (44%) | catalogued as rs747936667; called by muse, mutect2, varscan2
- UMOD | c.*113G>A | 3'UTR (SNP) | VAF 18/37 reads (49%) | called by muse, mutect2, varscan2
- VSTM5 | c.92-13del | Intron (DEL) | VAF 38/104 reads (37%) | called by mutect2, varscan2
- WNK3 | c.-6A>T | 5'UTR (SNP) | VAF 4/62 reads (6%) | called by muse, mutect2
- WNT5A | c.-80dup | 5'UTR (INS) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- XK | c.*2754T>A | 3'UTR (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- ZNF2 | chr2:95183434 G>A | 3'Flank (SNP) | VAF 55/117 reads (47%) | catalogued as rs935676000; called by muse, mutect2, varscan2
- ZNF528 | c.272-1005C>A | Intron (SNP) | VAF 3/47 reads (6%) | called by muse, mutect2
